Surgical pathology report (de-identified scan), TCGA case TCGA-86-8076, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8076-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

		OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path
Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy
Tumor site: Lung
Tumor size: 2.5 x 2.5 x 2.5
cm
Histologic type: Papillary
adenocarcinoma
Histologic grade: Well
differentiated
Tumor extent: Not
specified
Other tumor nodules: Not
specified
Lymph nodes: 0/5 positive
for metastasis (Regional
0/5)
Lymphatic invasion: Not
specified
Venous invasion: Not
specified
Margins: Not specified
Evidence of neo-adjuvant
treatment: Not specified
Additional pathologic
findings: Not specified
Comments: TTF1+, CD15+

Laterality

Right-upper

Excision date

Source: NCI Genomic Data Commons file 55a04665-a5b7-4a95-be5f-429c4f74a321 (TCGA-86-8076.C282D817-B99A-4BDA-8073-9DE1CAC074F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).